Somatic mutation profile of tumor specimen TARGET-10-PAPNNX-04A (aliquot TARGET-10-PAPNNX-04A-01D) from TARGET case TARGET-10-PAPNNX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,486 days).
Specimen TARGET-10-PAPNNX-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbf557fd-f047-45e0-914e-e5ef2a0014b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPNNX-10A (Blood Derived Normal), aliquot TARGET-10-PAPNNX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeaec386-26a2-4109-8a33-6138483f9c71

The open-access MAF lists 582 somatic variants for this specimen: 401 protein-altering or splice-affecting, 162 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 366, Silent 162, Nonsense Mutation 19, Splice Region 6, Intron 6, 3'UTR 4, Frame Shift Del 4, RNA 3, 5'UTR 3, Frame Shift Ins 3, Splice Site 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF12 | c.341G>A p.R114H (on ENST00000454309 / NM_021032.5; = p.R52H on NM_004113.6) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs886039903, CM166790, COSV53173851; ClinVar: pathogenic; called by muse, mutect2
- GHR | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 36/377 reads (10%) | catalogued as rs121909358, CM910179, COSV100049546; ClinVar: pathogenic; called by muse, mutect2
- MSH6 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 44/122 reads (36%) | catalogued as rs63750909, CM042402, COSV52288483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs63751113, CM021636, COSV52275309, COSV52291664; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516153, CM086015, COSV62516959; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 184/452 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC6A1 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 41/212 reads (19%) | catalogued as rs745529755, COSV55113671, COSV99822328; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1218862774, COSV57060101; called by muse, mutect2, varscan2
- ABCC3 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs764888307; called by mutect2, varscan2
- ABCC5 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV55595044; called by muse, mutect2
- ACAP3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV61223631; called by muse, mutect2, varscan2
- ACOT7 | c.1090C>T p.R364W (on ENST00000377855 / NM_181864.3; = p.R354W on NM_007274.4) | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781024703, COSV64111974; called by muse, mutect2, varscan2
- ACSM4 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756182664, COSV68066508; called by muse, mutect2, varscan2
- ACTA1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 3/57 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as CM034495, COSV64204280; called by muse, mutect2
- ADAM9 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 62/690 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1356814954, COSV65962598; called by muse, mutect2
- ADAMTS6 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1442947114, COSV66862199; called by muse, mutect2, varscan2
- ADCY8 | c.2647C>T p.R883C | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs780153239, COSV53928371; called by muse, mutect2
- ADGRB3 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 281/645 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394549289, COSV53236562, COSV53247358; called by muse, mutect2, varscan2
- ADGRD1 | c.1254C>T p.H418= | Splice Region (SNP) | VAF 12/71 reads (17%) | catalogued as COSV55444394, COSV55457718; called by muse, mutect2, varscan2
- ADGRE1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 61/486 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs772948778, COSV51673784, COSV51677393; called by muse, mutect2, varscan2
- AIFM3 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.284); catalogued as rs1304124990, COSV53151828; called by muse, mutect2, varscan2
- ALDOC | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs530097176; called by mutect2, varscan2
- ALPP | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs530857701, COSV67398099; called by muse, mutect2, varscan2
- ALS2CL | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757762540; called by muse, mutect2, varscan2
- AMER3 | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs777912797, COSV58466629, COSV58470366; called by muse, mutect2, varscan2
- ANK1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.796); catalogued as rs749015064, COSV55896154; called by mutect2, varscan2
- ANKRD11 | c.4540C>T p.L1514F | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1567568432, COSV56372305; called by muse, mutect2
- APBB2 | c.1654C>T p.R552W (on ENST00000295974 / NM_001166050.2; = p.R553W on NM_004307.2) | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs776253380, COSV55951872; called by muse, mutect2, varscan2
- APCS | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 19/304 reads (6%) | catalogued as rs879661012, COSV54817191; called by muse, mutect2
- AQR | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 44/474 reads (9%) | catalogued as rs1025139495, COSV50054564; called by muse, mutect2
- ARHGEF17 | c.3767G>A p.R1256Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as rs181690989, COSV55238297; called by mutect2, varscan2
- ARL4D | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60721872, COSV60721940; called by muse, mutect2, varscan2
- ATG2B | c.3811G>A p.V1271I | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.4); catalogued as rs766450496, COSV55892140; called by muse, mutect2, varscan2
- ATG4A | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs774160022, COSV58964652; called by muse, mutect2
- ATP11B | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60033462; called by muse, mutect2, varscan2
- ATP1B3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 38/443 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149675336; called by muse, mutect2
- ATP6V0A4 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.945); catalogued as rs753832938, COSV59475995; called by muse, mutect2, varscan2
- ATP8A2 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs373188486; called by muse, mutect2
- B3GNT7 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs375999431; called by mutect2, varscan2
- B3GNT7 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1044005987, COSV55006205; called by muse, mutect2
- BCAR3 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 9/135 reads (7%) | catalogued as rs1557836909, COSV53073095; called by muse, mutect2
- BEX2 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs1470330345, COSV65500828, COSV65500935; called by muse, mutect2, varscan2
- BOLL | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.638); catalogued as rs1432014139, COSV56577569; called by muse, mutect2
- BPNT1 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 18/686 reads (3%) | catalogued as rs975663071, COSV59041531; called by muse, mutect2
- BSN | c.10069C>T p.R3357C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374322298; called by muse, varscan2
- BTBD19 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV69768419; called by muse, mutect2, varscan2
- BTBD7 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1044755895, COSV54139138; called by muse, mutect2
- C11orf16 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs750826585, COSV58169134; called by muse, mutect2, varscan2
- C14orf180 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs771626473, COSV59557925; called by muse, mutect2, varscan2
- CAMSAP2 | c.1639C>T p.Q547* (on ENST00000236925 / NM_001297707.2; = p.Q536* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV52677549; called by muse, mutect2, varscan2
- CAPN12 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs148606134, COSV61018747; called by muse, mutect2, varscan2
- CAPN6 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 133/156 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60695041; called by muse, mutect2, varscan2
- CAPNS2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs754652916, COSV50900036; called by muse, mutect2, varscan2
- CARS2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 56/355 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569211240, COSV57289161; called by muse, mutect2, varscan2
- CASP8AP2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs751345809, COSV52745680, COSV52750022; called by muse, varscan2
- CC2D1A | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV58786281; called by muse, mutect2
- CCDC43 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs759647993, COSV59520768; called by muse, mutect2, varscan2
- CCDC50 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs557807225, COSV66668580, COSV66669754; called by muse, mutect2, varscan2
- CCNB2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs1480149587; called by muse, mutect2
- CCNE1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1352565996, COSV52905837; called by muse, mutect2
- CD164L2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.284); catalogued as rs752238611, COSV64995446; called by muse, mutect2, varscan2
- CD9 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs190218669, CM156954, COSV50530680; called by muse, mutect2
- CDHR1 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.282); catalogued as rs545329607, COSV60566345; called by muse, mutect2, varscan2
- CDK8 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV67420618; called by muse, mutect2, varscan2
- CELSR2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs537085166, COSV54775270; called by muse, mutect2, varscan2
- CELSR2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54779467; called by muse, mutect2, varscan2
- CELSR2 | c.4939C>T p.R1647C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150642712, COSV99604791; called by mutect2, varscan2
- CEP170B | c.2266G>A p.G756R (on ENST00000453495; = p.G685R on NM_015005.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1281802978; called by muse, varscan2
- CERKL | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); catalogued as rs529313774, COSV100183746, COSV59213105; called by muse, mutect2
- CFAP45 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1483238059, COSV63651146; called by muse, mutect2, varscan2
- CFAP70 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60286981; called by muse, mutect2, varscan2
- CFHR3 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.713); catalogued as rs574536456, COSV66401862; called by muse, mutect2
- CHD2 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs1060503521, COSV67714532; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHPF | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as rs750764885, COSV60535947; called by muse, mutect2, varscan2
- CHRM3 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55089710; called by muse, mutect2, varscan2
- CIPC | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62376795; called by muse, mutect2
- CLEC12A | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs761984982, COSV58562718; called by muse, mutect2
- CNGA3 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs769370731, COSV55624881; called by mutect2, varscan2
- CNOT4 | c.1514G>A p.R505H (on ENST00000315544 / NM_001190848.1; = p.R502H on NM_013316.4) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs777344165, COSV59654634; called by muse, mutect2, varscan2
- CNST | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754661102, COSV100830250, COSV63624397; called by muse, mutect2
- CNTRL | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs369768072, COSV53046774; called by muse, mutect2
- COL12A1 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557804521, COSV59408187; called by muse, mutect2, varscan2
- COL18A1 | c.1805C>T p.P602L (on ENST00000359759 / NM_130444.3; = p.P367L on NM_030582.4) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs768416568, COSV62706456; called by muse, mutect2, varscan2
- COL6A3 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs369460632, COSV55086518; called by mutect2, varscan2
- COL6A3 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs201249839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLGALT1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs139673867, COSV53111614; called by muse, mutect2, varscan2
- COPA | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54098957; called by muse, mutect2, varscan2
- COPG1 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV59116544; called by muse, mutect2
- CRYAB | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs1264081192, COSV57052894; called by muse, mutect2, varscan2
- CSPP1 | c.2809C>T p.R937C (on ENST00000676605; = p.R896C on NM_024790.6) | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs757750162, COSV51580167; ClinVar: uncertain significance; called by muse, mutect2
- CYFIP1 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs199596519; called by muse, mutect2, varscan2
- CYP2C18 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs545798981, COSV53670838; called by muse, varscan2
- CYTH3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV63441429; called by muse, mutect2, varscan2
- DAAM2 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); catalogued as rs192352327; called by muse, mutect2, varscan2
- DCAF1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.361); catalogued as rs782390664, COSV60045488; called by muse, mutect2, varscan2
- DHX38 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs753722533, COSV51696673; called by muse, mutect2
- DIP2C | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs199745501, COSV55179569; called by muse, mutect2
- DIPK1C | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs1294519362, COSV59726651; called by muse, mutect2
- DMTN | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56114658; called by muse, mutect2, varscan2
- DNAH7 | c.10900C>T p.R3634W | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1327486699, COSV56786986; called by muse, mutect2, varscan2
- DNMT1 | c.755+1G>A p.X252_splice | Splice Site (SNP) | VAF 95/508 reads (19%) | catalogued as COSV61583992; called by muse, mutect2, varscan2
- DOCK1 | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs765597446; called by muse, mutect2
- DOCK10 | c.5636G>A p.R1879H | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761407402, COSV51346733, COSV51421387; called by muse, mutect2, varscan2
- DPY19L3 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as COSV60480284; called by muse, mutect2
- DPYS | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs150948846, COSV100679122, COSV60908630; called by muse, varscan2
- DRC7 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs1168634706, COSV61055565; called by muse, mutect2
- DROSHA | c.2241G>A p.T747= | Splice Region (SNP) | VAF 15/126 reads (12%) | catalogued as COSV60779427; called by muse, mutect2, varscan2
- DSG2 | c.1657A>G p.S553G | Missense Mutation (SNP) | VAF 75/309 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV55203005; called by muse, mutect2, varscan2
- DSG3 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749070413, COSV57129773; called by muse, mutect2, varscan2
- DZANK1 | c.1981G>A p.V661M (on ENST00000262547 / NM_001099407.1; = p.V468M on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs766364620, COSV52757136; called by muse, mutect2
- EHBP1 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772247910, COSV50438819; called by muse, mutect2, varscan2
- EPHB3 | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1357171765, COSV57809186; called by muse, mutect2, varscan2
- ERAP2 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs201095797, COSV65941444; called by muse, mutect2, varscan2
- ESX1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.053); catalogued as COSV65425186; called by muse, mutect2, varscan2
- EVC2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs539685245, COSV60387244; called by muse, mutect2, varscan2
- EXPH5 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 16/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56208453; called by muse, mutect2
- FAM20A | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as rs1011574385, COSV56838388; called by muse, mutect2, varscan2
- FAM47E | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); catalogued as rs1350154584, COSV60534285; called by muse, mutect2
- FBN3 | c.445+1G>C p.X149_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | catalogued as COSV54473360; called by muse, mutect2, varscan2
- FCGR2B | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs373810561; called by muse, mutect2
- FGF11 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1206968256, COSV53439418; called by muse, mutect2, varscan2
- FN1 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs748700094, COSV60564483; called by muse, mutect2
- FOXL1 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV57213788, COSV57213966; called by muse, mutect2, varscan2
- FOXO1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs994659376, COSV65428337; called by muse, mutect2, varscan2
- G3BP2 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 51/568 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62975877, COSV62977709; called by muse, mutect2
- GAB1 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs55997904, COSV53761100; called by muse, mutect2, varscan2
- GABRG2 | c.1121C>T p.A374V (on ENST00000361925 / NM_001375343.1; = p.A334V on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/689 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs1415043929, COSV62722149; called by muse, mutect2
- GABRR1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201013212, COSV65619294; called by muse, mutect2, varscan2
- GATA2 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.134); catalogued as rs369637181; ClinVar: uncertain significance; called by muse, varscan2
- GCA | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs563127943, COSV52026884; called by muse, mutect2, varscan2
- GCFC2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 43/1010 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs373951174, COSV58082874; called by muse, mutect2
- GLIPR1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 14/403 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1035682004; called by muse, mutect2
- GNAI2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553703484; called by muse, mutect2
- GNAQ | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV54125773; called by muse, mutect2, varscan2
- GPR18 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 59/416 reads (14%) | catalogued as rs955035338, COSV61621529; called by muse, mutect2, varscan2
- GPSM3 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1416793659, COSV66683912; called by muse, mutect2
- GRAMD1C | c.459G>A p.K153= | Splice Region (SNP) | VAF 37/254 reads (15%) | catalogued as rs1258192009, COSV63984632; called by muse, mutect2, varscan2
- GRIA1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs748631549, COSV53625070; called by muse, mutect2, varscan2
- GRIA1 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 28/273 reads (10%) | catalogued as COSV53625087; called by muse, mutect2, varscan2
- GUCY1A1 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746638427, COSV56656639; called by muse, mutect2, varscan2
- HAAO | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.299); catalogued as rs759103777, COSV54313194; called by muse, mutect2, varscan2
- HCCS | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772248528, COSV58239739; called by muse, mutect2
- HCN4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.06); catalogued as rs368164073, COSV56085738; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCRTR1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs530187593, COSV65486747; called by muse, mutect2, varscan2
- HDAC5 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1233219591, COSV56822034; called by muse, mutect2, varscan2
- HDAC9 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1054512034, COSV101286646; called by muse, mutect2
- HECW2 | c.3094C>T p.R1032W | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1157963107, COSV53674597; called by muse, mutect2, varscan2
- HEPH | c.202C>T p.R68W (on ENST00000343002; = p.R122W on NM_138737.5) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748484259, COSV57960210; called by muse, mutect2, varscan2
- HERC1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs544246854, COSV71250310; called by muse, mutect2, varscan2
- HERC4 | c.2261G>A p.R754H (on ENST00000395198 / NM_022079.3; = p.R746H on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs753652704, COSV53270657; called by muse, mutect2, varscan2
- HERC6 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 46/399 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs371365965; called by muse, varscan2
- HGSNAT | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs753112671, COSV52819201; called by muse, mutect2, varscan2
- HPX | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs559750586, COSV56419568; called by muse, mutect2
- HTR1D | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs185525977, COSV58449482; called by muse, mutect2, varscan2
- HUWE1 | c.5975G>A p.R1992Q | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.455); catalogued as rs199846544, COSV53364192; called by muse, mutect2, varscan2
- ISL1 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57934619; called by muse, mutect2, varscan2
- ISL1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100045222; called by muse, mutect2
- ITGAD | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.746); catalogued as rs1378391764, COSV66760268; called by muse, mutect2, varscan2
- ITGB4 | c.4354C>T p.P1452S | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.077); catalogued as rs953074039, COSV52326885, COSV52332930; called by muse, mutect2, varscan2
- ITLN2 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs749561519, COSV63538254; called by muse, mutect2
- ITPR1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as COSV56994203; called by muse, mutect2, varscan2
- JAKMIP1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774810031, COSV51545691; called by mutect2, varscan2
- KCNN1 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55838709; called by muse, mutect2, varscan2
- KIF21B | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs953396132, COSV59766970; called by muse, mutect2
- KIF4A | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV65544057, COSV65546003; called by muse, mutect2, varscan2
- KIN | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs61752337, COSV65431526; called by muse, mutect2, varscan2
- KLK13 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs757744045, COSV50067608; called by muse, mutect2, varscan2
- KMT2C | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV51381231; called by muse, mutect2
- KRT19 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV64239348; called by muse, mutect2, varscan2
- KXD1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.215); catalogued as rs548226037, COSV55890558; called by mutect2, varscan2
- KYNU | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs146601376, COSV51581861; called by muse, varscan2
- LAMA2 | c.5285G>A p.R1762Q | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.509); catalogued as rs138296015, COSV101370451, COSV70355297; called by muse, mutect2, varscan2
- LCLAT1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58371868; called by muse, mutect2, varscan2
- LIPG | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs756501637, COSV54296849; called by muse, mutect2, varscan2
- LNP1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs193190932, COSV67346315; called by muse, mutect2
- LONRF2 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199079623; called by muse, mutect2
- LOXL3 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1353900393, COSV51214283; called by muse, mutect2, varscan2
- LRGUK | c.455A>C p.Q152P | Missense Mutation (SNP) | VAF 135/676 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV53643891; called by muse, mutect2, varscan2
- LRP2 | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368997664; called by muse, mutect2, varscan2
- LRRC25 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV59114974; called by muse, mutect2, varscan2
- LY75 | c.4564C>T p.R1522C | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs766221795, COSV55103780; called by muse, mutect2, varscan2
- LYPD4 | c.67+1G>A p.X23_splice | Splice Site (SNP) | VAF 12/242 reads (5%) | catalogued as rs782812231, COSV58027470; called by muse, mutect2
- MAB21L4 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs368820404; called by muse, mutect2, varscan2
- MACF1 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 11/259 reads (4%) | catalogued as COSV58403067; called by muse, mutect2
- MAN2B2 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs202106040, COSV53456924; called by muse, mutect2, varscan2
- MAP3K13 | c.2659G>A p.D887N | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.646); catalogued as rs889834349, COSV53997842; called by muse, mutect2, varscan2
- MAP3K4 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as rs764381750, COSV62335561; called by muse, mutect2
- MAP3K8 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53921231, COSV53921741; called by muse, mutect2
- MAP7D1 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60214987; called by muse, varscan2
- MAPK4 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); catalogued as rs761581511, COSV68542087; called by muse, mutect2, varscan2
- MBNL2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1275398220, COSV59122324, COSV59123246; called by muse, mutect2
- MEGF8 | c.2962G>A p.G988R (on ENST00000251268 / NM_001271938.2; = p.G921R on NM_001410.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs764510742, COSV52102046; called by muse, mutect2, varscan2
- METAP2 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs1360276323, COSV51567194; called by muse, mutect2, varscan2
- MFSD14A | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.081); catalogued as COSV64515386; called by muse, mutect2, varscan2
- MLXIPL | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); catalogued as rs782479538; called by muse, mutect2
- MMRN2 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs763827897, COSV64400331; called by muse, mutect2, varscan2
- MOK | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs912683364, COSV51967747; called by muse, mutect2, varscan2
- MPO | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762564974, COSV56569108; called by mutect2, varscan2
- MR1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 55/509 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs777324974, COSV51581327, COSV51581390; called by muse, mutect2, varscan2
- MRC1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 40/1468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53471239; called by muse, mutect2
- MRPL1 | c.708A>T p.L236F | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV59676392, COSV59676943; called by muse, mutect2
- MRPS21 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs773014515, COSV58414663; called by muse, mutect2, varscan2
- MSI1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as COSV57457843; called by muse, mutect2, varscan2
- MTA1 | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs782370721, COSV58760492; called by muse, mutect2
- MTIF2 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 35/413 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs200247481, COSV55054291; called by muse, mutect2
- MTM1 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs781895025, COSV60335226; called by muse, mutect2, varscan2
- MTUS2 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376698099; called by muse, mutect2, varscan2
- MUC16 | c.17114C>T p.A5705V | Missense Mutation (SNP) | VAF 56/602 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as rs200898366; called by muse, mutect2
- MVP | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs775063563, COSV62423572; called by muse, mutect2
- MYL7 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs376123400; called by muse, mutect2, varscan2
- MYO18A | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV62873532; called by muse, mutect2, varscan2
- MYO5C | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV55912237; called by muse, mutect2, varscan2
- MYO9A | c.5153G>A p.R1718Q | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.767); catalogued as rs968502392, COSV61848564; called by muse, mutect2
- MYO9A | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762897653, COSV61858019; called by muse, mutect2
- NAA16 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1313404485, COSV65065878; called by muse, mutect2
- NBPF9 | c.2721T>G p.F907L | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1456947604; called by muse, varscan2
- NCOR1 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1434823254, COSV51996526; called by muse, mutect2, varscan2
- NDUFS2 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1452781166, COSV57156161; called by muse, mutect2
- NEB | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs116678485, COSV51446818; called by muse, mutect2
- NEDD4L | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs752858201, COSV56839879; called by mutect2, varscan2
- NEDD8 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV51660485; called by muse, mutect2, varscan2
- NFRKB | c.296G>A p.R99H (on ENST00000446488 / NM_001143835.2; = p.R112H on NM_006165.3) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs749164897, COSV58757836, COSV58760583; called by muse, mutect2
- NFU1 | c.712G>A p.V238I (on ENST00000410022 / NM_001002755.4; = p.V214I on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs750485783, COSV58007685; called by muse, mutect2
- NIBAN1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 34/604 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.938); catalogued as rs562448693, COSV62284129; called by muse, mutect2
- NOD1 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770494099, COSV56114822; called by muse, mutect2, varscan2
- NOD1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 78/350 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750433986, COSV56114829; called by muse, mutect2, varscan2
- NOL10 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 52/922 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs368376128, COSV62040457; called by muse, mutect2
- NOL12 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs567310599, COSV63031830; called by muse, mutect2, varscan2
- NOX1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); catalogued as rs140487076, COSV54196694; called by muse, mutect2, varscan2
- NR2E3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1205711731, COSV58907651; called by muse, mutect2, varscan2
- NSD3 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs373265367, COSV57666573, COSV57671312; called by muse, varscan2
- NSUN7 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs765997254, COSV55954964; called by muse, mutect2
- OGFOD1 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308181915, COSV60201556; called by muse, mutect2
- OPHN1 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1191253744; called by muse, mutect2
- OR52B2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs998624811, COSV73209607, COSV73209660; called by muse, mutect2, varscan2
- OR6C65 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as rs770115073, COSV65569474; called by muse, mutect2, varscan2
- PAFAH2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs764886446, COSV65340265; called by muse, mutect2
- PASK | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV52160728; called by muse, mutect2, varscan2
- PCDH12 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs374457419; called by muse, varscan2
- PCDHA3 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV63539069; called by mutect2, varscan2
- PCDHB12 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as rs782816498, COSV53400242, COSV53401170; called by muse, mutect2
- PCDHB13 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.431); catalogued as rs782354480, COSV53401173; called by muse, mutect2, varscan2
- PCDHB2 | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as rs1554271704, COSV50609601; called by muse, mutect2
- PCDHB5 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs1182162920, COSV50655601; called by muse, mutect2, varscan2
- PCDHGA5 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV54014928; called by muse, mutect2, varscan2
- PCDHGB5 | c.2378C>T p.S793L | Missense Mutation (SNP) | VAF 83/787 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs759107285, COSV53988478; called by muse, mutect2, varscan2
- PDIA5 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1383941343, COSV60250387; called by muse, mutect2, varscan2
- PDK1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV56375338; called by muse, mutect2, varscan2
- PDZD2 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56854841; called by muse, mutect2
- PEAK1 | c.5237G>A p.R1746H | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs765543180, COSV56935467; called by muse, mutect2, varscan2
- PEG3 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs764907402, COSV55624386; called by muse, mutect2, varscan2
- PGGHG | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs376449048; called by muse, mutect2, varscan2
- PGLS | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs375302944; called by muse, mutect2, varscan2
- PHLDB2 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs548907756, COSV67315209, COSV67316228; called by muse, mutect2
- PHRF1 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1351491471, COSV52762965; called by muse, mutect2, varscan2
- PIGT | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.431); catalogued as rs770815793, COSV54125095; called by muse, mutect2, varscan2
- PIK3C2G | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs186647102, COSV56817686, COSV56819548; called by muse, varscan2
- PIK3R4 | c.3724G>A p.V1242I | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs766101846, COSV100650921, COSV62038128; called by muse, varscan2
- PLA2G3 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs751736495, COSV53212803; called by mutect2, varscan2
- PLCG2 | c.3098G>A p.R1033H | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.441); catalogued as rs760293225, COSV63876508; called by muse, mutect2, varscan2
- PLCXD1 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as rs750805878; called by muse, mutect2
- PLEC | c.7114G>A p.V2372M (on ENST00000322810 / NM_201380.4; = p.V2262M on NM_000445.5) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs782255133, COSV59630502, COSV59696215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHB1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs1392019589, COSV57049130, COSV57050505; called by muse, mutect2, varscan2
- PLLP | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.747); catalogued as rs199955338, COSV54656822; called by muse, mutect2, varscan2
- POMT2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs571330846, COSV55074075; called by muse, mutect2, varscan2
- POU2AF1 | c.147G>A p.A49= | Splice Region (SNP) | VAF 8/74 reads (11%) | catalogued as COSV67577797; called by muse, varscan2
- POU4F3 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV57945030; called by muse, mutect2, varscan2
- PPEF1 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1030784745, COSV62995785; called by muse, mutect2, varscan2
- PRAMEF1 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.972); catalogued as rs532097770, COSV60005314, COSV60014233; called by muse, mutect2, varscan2
- PRDM11 | c.280C>T p.R94C (on ENST00000530656 / NM_001359633.1; = p.R60C on NM_001256695.1) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55443852; called by muse, mutect2, varscan2
- PRIMPOL | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 82/813 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs150948050; called by muse, varscan2
- PRKAA1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1263050834, COSV57186443; called by muse, mutect2, varscan2
- PRKCG | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs376704133, COSV54733181; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCI | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); catalogued as rs1254638218, COSV55522695; called by muse, mutect2, varscan2
- PRKCQ | c.2098G>A p.G700R | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.117); catalogued as rs748100103, COSV54112707; called by muse, mutect2
- PRR5L | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs755502225, COSV61123573; called by mutect2, varscan2
- PSEN1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs149299753; called by muse, mutect2, varscan2
- PSPC1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1174051458, COSV58886431; called by muse, mutect2
- PTCD1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775141794, COSV52867859; called by muse, mutect2, varscan2
- PTCH2 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); catalogued as rs1366049289; called by muse, mutect2, varscan2
- PTGIS | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs566137707, COSV54840724; called by muse, mutect2, varscan2
- PTPRM | c.4174G>A p.G1392R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755503991, COSV59870129; called by muse, mutect2, varscan2
- PTPRT | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as rs775796300, COSV61957360; called by muse, mutect2, varscan2
- RAB11A | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV99976876; called by muse, mutect2
- RAPGEF6 | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 26/361 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs868107184, COSV57247473; called by muse, mutect2
- RARS2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746885661, COSV65762816; called by muse, mutect2, varscan2
- RD3 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs145054188; called by muse, mutect2, varscan2
- REG4 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs747842213, COSV56654028; called by muse, mutect2, varscan2
- RELCH | c.3425G>A p.R1142Q | Missense Mutation (SNP) | VAF 59/584 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.397); catalogued as rs370738160, COSV56881516; called by muse, mutect2
- RFX3 | c.1200G>A p.S400= | Splice Region (SNP) | VAF 30/362 reads (8%) | catalogued as rs143518057; called by muse, mutect2
- RGN | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781867031, COSV60276897; called by muse, mutect2, varscan2
- RHAG | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 10/140 reads (7%) | catalogued as rs1397420527, COSV57704797; called by muse, mutect2
- RHEX | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782181485, COSV58980749; called by muse, mutect2
- RMND5B | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 12/186 reads (6%) | catalogued as rs746249251, COSV57744108; called by muse, mutect2
- RNF123 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.987); catalogued as rs1300720354, COSV59692593; called by muse, mutect2, varscan2
- ROBO3 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV67302906; called by muse, mutect2
- ROR2 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs758358702, COSV65216799; called by mutect2, varscan2
- RPL22 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV52379371; called by muse, mutect2, varscan2
- RUNX1 | c.539G>A p.R180Q (on ENST00000344691 / NM_001001890.3; = p.R207Q on NM_001754.5) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1229231012, CM137026, COSV100276796, COSV55881119, COSV55884643; ClinVar: uncertain significance; called by muse, mutect2
- SACM1L | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs779832720, COSV66615269; called by muse, mutect2, varscan2
- SACS | c.6278G>A p.R2093H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs150018812; called by muse, mutect2, varscan2
- SCAF4 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); catalogued as rs908477707, COSV54592335; called by muse, mutect2
- SCAMP3 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371626936; called by muse, mutect2
- SCN5A | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs911293694, COSV61129734; called by muse, mutect2
- SCN5A | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs199473580, CM097648, COSV61141190; ClinVar: not provided; called by muse, mutect2, varscan2
- SDK2 | c.4903G>A p.A1635T | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs780372738, COSV66183343, COSV66184361; called by muse, mutect2, varscan2
- SERPIND1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 24/264 reads (9%) | catalogued as rs776318030, COSV53140965; called by muse, mutect2
- SH2D1A | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 26/527 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM014961, CM110892, COSV63578771, COSV63579248; called by muse, mutect2
- SH3TC2 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233598157, COSV60462941; called by muse, mutect2, varscan2
- SLC22A4 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 40/302 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs762018264, COSV52358992, COSV99569465; called by muse, mutect2, varscan2
- SLC24A2 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747399989, COSV53862090; called by muse, mutect2, varscan2
- SLC27A2 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs150689218; called by muse, mutect2, varscan2
- SMAD1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV57473504; called by muse, mutect2, varscan2
- SMAP2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65533713, COSV65534297; called by muse, mutect2
- SMARCA4 | c.1941G>A p.P647= | Splice Region (SNP) | VAF 12/87 reads (14%) | catalogued as rs369866257, COSV100758419; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMARCA5 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 61/485 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866583525, COSV51647371; called by muse, varscan2
- SMG6 | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769949146; called by muse, varscan2
- SNRPN | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs775190561, COSV57594364, COSV57599888; called by muse, mutect2, varscan2
- SOX5 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1170998452, COSV58618046, COSV58648980; called by muse, mutect2
- SPEG | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs758282857, COSV56679940; called by mutect2, varscan2
- ST3GAL5 | c.529G>A p.D177N (on ENST00000377332; = p.D217N on NM_003896.4) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767789131, COSV60385231; called by muse, mutect2, varscan2
- STARD9 | c.9235G>A p.V3079M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs892636977, COSV51915109; called by muse, mutect2
- STX3 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as rs751095384, COSV55701431; called by muse, mutect2
- SULF1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs186655894, COSV52693584; called by muse, mutect2, varscan2
- SVOPL | c.749G>A p.R250H (on ENST00000419765; = p.R98H on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as rs149283565; called by muse, varscan2
- TAF15 | c.1184G>A p.R395Q (on ENST00000605844 / NM_139215.3; = p.R392Q on NM_003487.4) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs71381481, CM113415; called by muse, mutect2, varscan2
- TAGLN3 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56329609; called by muse, mutect2, varscan2
- TBC1D14 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.17); catalogued as rs371738551; called by mutect2, varscan2
- TBL1Y | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1431838068, COSV60733949; called by muse, mutect2
- TDRD5 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 28/399 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs771332017, COSV54250734; called by muse, mutect2
- TEN1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 81/383 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs376979590, COSV67120357; called by muse, mutect2, varscan2
- TES | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs767751593, COSV64043733; called by muse, mutect2, varscan2
- TKTL1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs781822420; called by muse, mutect2
- TLN2 | c.6826C>T p.R2276* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100167869, COSV60892297; called by muse, mutect2
- TMEM154 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs147009220; called by muse, mutect2, varscan2
- TMPRSS13 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs778644730, COSV70625527; called by muse, mutect2, varscan2
- TNFRSF18 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs371599555; called by muse, mutect2, varscan2
- TNFRSF25 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs184760605, COSV61069710; called by muse, mutect2, varscan2
- TP53BP2 | c.1828G>A p.V610M (on ENST00000343537 / NM_001031685.3; = p.V481M on NM_005426.2) | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV59073162; called by muse, mutect2, varscan2
- TRAV20 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs35737142; called by muse, mutect2, varscan2
- TRIM28 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53401813; called by muse, mutect2, varscan2
- TRIO | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761067835, COSV60096123; called by muse, mutect2, varscan2
- TRPC7 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs770873060, COSV61456484; called by muse, mutect2
- TSPAN17 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs777541888, COSV53780238; called by muse, mutect2, varscan2
- TTC17 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 18/451 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50020918; called by muse, mutect2
- TTC21B | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs760903357, COSV54635370; called by muse, mutect2, varscan2
- TTN | c.83744G>A p.R27915Q (on ENST00000591111; = p.R20491Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/192 reads (5%) | PolyPhen benign (0); catalogued as rs1207034709, COSV60202461; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.52019C>T p.A17340V (on ENST00000591111; = p.A9916V on NM_003319.4) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | PolyPhen benign (0); catalogued as rs397517627, COSV60302455; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / benign; called by muse, mutect2, varscan2
- TTN | c.26962C>T p.R8988* (on ENST00000591111; = p.R8061* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/184 reads (11%) | catalogued as rs1553889325, COSV60118500; ClinVar: uncertain significance; called by muse, mutect2
- TUB | c.92G>A p.R31Q (on ENST00000299506 / NM_177972.3; = p.R86Q on NM_003320.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs765032093; called by muse, mutect2, varscan2
- UBA1 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs149161653, COSV60113000; called by muse, mutect2, varscan2
- UBE2G2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782636745, COSV58369198; called by muse, mutect2
- UBE2O | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775817471, COSV60067797; called by muse, mutect2, varscan2
- UNC13B | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs368700689; called by muse, mutect2, varscan2
- USP11 | c.1874G>A p.R625H (on ENST00000218348; = p.R582H on NM_001371072.1) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1157335115, COSV54476012; called by muse, mutect2, varscan2
- USP28 | c.2465A>T p.D822V | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173764114, COSV50192641; called by muse, mutect2
- UXS1 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs750633018; called by muse, mutect2
- VIT | c.1804G>A p.D602N (on ENST00000389975 / NM_001177969.1; = p.D617N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448272199, COSV101007606, COSV64898688; called by muse, mutect2
- VWA3B | c.1544C>T p.T515M | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770917627, COSV68246864; called by muse, mutect2, varscan2
- WDFY3 | c.8941C>T p.R2981* | Nonsense Mutation (SNP) | VAF 74/338 reads (22%) | catalogued as COSV55699140; called by muse, mutect2, varscan2
- WDR27 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as rs763294437, COSV61216286; called by muse, mutect2, varscan2
- WDR33 | c.3923G>A p.R1308Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as rs1018871373, COSV59245941; called by muse, mutect2, varscan2
- WNT7A | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV53198092; called by muse, varscan2
- WWC1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.528); catalogued as rs750795143, COSV99515506; called by mutect2, varscan2
- XYLB | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs368027581; called by muse, mutect2, varscan2
- ZAN | c.7901G>A p.R2634H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs369341019; called by mutect2, varscan2
- ZBTB41 | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 72/914 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.042); catalogued as rs759439448, COSV66359458; called by muse, mutect2
- ZC3H12C | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755516129, COSV53712975; called by muse, mutect2, varscan2
- ZCCHC13 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.613); catalogued as rs1170212113, COSV59866709; called by muse, mutect2
- ZDHHC11 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs1005846605, COSV52077310; called by muse, mutect2
- ZFR2 | c.2020G>T p.V674L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53601840, COSV53602069; called by muse, varscan2
- ZGRF1 | c.3055A>G p.M1019V | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58411427; called by muse, mutect2
- ZNF185 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs782484033, COSV59278232; called by muse, mutect2, varscan2
- ZNF207 | c.1157T>C p.L386P | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58302167; called by muse, mutect2, varscan2
- ZNF22 | c.671delinsCCC p.R224Pfs*8 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | catalogued as COSV53584526; called by pindel, varscan2*
- ZNF230 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444824642, COSV71273398; called by muse, mutect2
- ZNF236 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 35/338 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs748870968, COSV53482551; called by muse, mutect2, varscan2
- ZNF287 | c.2208A>G p.I736M | Missense Mutation (SNP) | VAF 51/488 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as rs746884737, COSV67689142; called by muse, mutect2, varscan2
- ZNF600 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs754308959, COSV57745336; called by muse, mutect2
- ZNF618 | c.496G>A p.V166M (on ENST00000374126 / NM_001318042.2; = p.V134M on NM_133374.2) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs773867867, COSV55929989; called by muse, mutect2, varscan2
- ZNF623 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs765799494, COSV71697124; called by muse, mutect2
- ZNF71 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60150302; called by muse, mutect2
- ZNF778 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs565404494, COSV60602834; called by muse, mutect2, varscan2
- ZNF793 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs759729464, COSV71324934; called by muse, mutect2, varscan2
- ZNF821 | c.851G>A p.R284Q (on ENST00000425432 / NM_001376297.1; = p.R242Q on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.294); catalogued as rs374644793; called by muse, mutect2, varscan2
- ACACA | c.4550C>T p.T1517M | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- C8orf34 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2
- CSGALNACT1 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2D | c.1143dup p.T382Hfs*2 | Frame Shift Ins (INS) | VAF 42/133 reads (32%) | called by mutect2, pindel, varscan2
- KMT2D | c.508_509del p.Q170Afs*49 | Frame Shift Del (DEL) | VAF 50/142 reads (35%) | called by pindel, varscan2
- LHFPL4 | c.182del p.L61Pfs*45 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel
- NFATC2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NOX5 | c.1407del p.H470Tfs*10 | Frame Shift Del (DEL) | VAF 29/218 reads (13%) | called by mutect2, pindel, varscan2
- PLXNB1 | c.4742G>A p.R1581H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.742); called by muse, mutect2
- PPP3CC | c.1216_1217insGGTCGGAC p.I406Rfs*13 | Frame Shift Ins (INS) | VAF 112/332 reads (34%) | called by pindel, varscan2
- SLITRK5 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 5/117 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- SNAP91 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SOGA3 | c.2548G>A p.G850R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- TBC1D17 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); called by muse, mutect2
- TSPAN15 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.379); called by muse, mutect2
- UBA2 | c.774_777del p.F259Kfs*8 | Frame Shift Del (DEL) | VAF 98/320 reads (31%) | called by pindel*, varscan2
- ABCA3 | c.2349C>T p.N783= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs770587856, COSV57052640; called by muse, varscan2
- ABCA4 | c.6270G>A p.P2090= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs755217474, COSV64678213; called by muse, mutect2, varscan2
- ABCC4 | c.1092G>A p.T364= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1236209020, COSV65318446; called by muse, mutect2, varscan2
- ABCC9 | c.1290G>T p.L430= | Silent (SNP) | VAF 114/239 reads (48%) | catalogued as COSV53981403; called by muse, mutect2, varscan2
- ADGRG6 | c.2655A>G p.T885= | Silent (SNP) | VAF 184/414 reads (44%) | catalogued as rs376656716; called by muse, mutect2, varscan2
- AFAP1L1 | c.576C>T p.Y192= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs767999558, COSV57047864; called by muse, mutect2, varscan2
- ALDH3A1 | c.570G>A p.T190= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs370424410, COSV99855852; called by muse, mutect2
- ALOX12 | c.267C>T p.C89= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV52352271; called by muse, mutect2
- ANKAR | c.1791G>A p.T597= | Silent (SNP) | VAF 24/217 reads (11%) | catalogued as rs555194963, COSV55611147; called by muse, mutect2, varscan2
- ARHGEF1 | c.339G>A p.P113= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs201880696; called by muse, mutect2, varscan2
- ATCAY | c.957C>T p.C319= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs370680121, COSV100009001; ClinVar: uncertain significance; called by mutect2, varscan2
- ATP13A3 | c.2703G>A p.S901= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as rs552421375, COSV55469695, COSV99756261; called by muse, mutect2, varscan2
- ATP2B1 | c.3285C>T p.H1095= | Silent (SNP) | VAF 30/390 reads (8%) | catalogued as rs377632094, COSV53812996; called by muse, mutect2
- ATP2C1 | c.579G>A p.T193= | Silent (SNP) | VAF 16/300 reads (5%) | catalogued as rs1203670242, COSV60762938; called by muse, mutect2
- ATP7B | c.3489C>T p.S1163= | Silent (SNP) | VAF 28/299 reads (9%) | catalogued as rs193922106; ClinVar: likely benign; called by muse, mutect2
- B4GALT3 | c.687G>A p.P229= | Silent (SNP) | VAF 40/246 reads (16%) | catalogued as rs200680049, COSV60527324; called by muse, mutect2, varscan2
- BCLAF1 | c.534G>A p.P178= | Silent (SNP) | VAF 58/632 reads (9%) | catalogued as rs369195148, COSV62142934; called by muse, mutect2
- BRD3 | c.945C>T p.C315= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs200782945; called by muse, mutect2
- BRSK1 | c.219G>A p.S73= | Silent (SNP) | VAF 20/213 reads (9%) | catalogued as rs760341371, COSV58664533; called by muse, mutect2
- BTNL8 | c.600C>T p.N200= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as rs377605273; called by muse, mutect2, varscan2
- C12orf56 | c.432C>T p.N144= | Silent (SNP) | VAF 40/218 reads (18%) | catalogued as rs370367135; called by muse, mutect2, varscan2
- C1QTNF2 | c.741G>A p.T247= (on ENST00000393975; = p.T202= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs754655270, COSV67433355; called by muse, mutect2, varscan2
- C1QTNF5 | c.516C>T p.G172= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV60990722; called by mutect2, varscan2
- CACNA1I | c.471C>T p.I157= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as rs764533152, COSV60814475; called by muse, mutect2, varscan2
- CACNA2D4 | c.729G>A p.T243= | Silent (SNP) | VAF 33/239 reads (14%) | catalogued as rs1028322197, COSV54960979; called by muse, mutect2, varscan2
- CASQ1 | c.807G>A p.P269= | Silent (SNP) | VAF 26/375 reads (7%) | catalogued as rs375200941, COSV63624567; called by muse, mutect2
- CATSPER4 | c.615C>T p.R205= | Silent (SNP) | VAF 36/201 reads (18%) | catalogued as rs759483299, COSV58794724; called by muse, mutect2, varscan2
- CCDC134 | c.477G>A p.S159= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs773419482; called by muse, mutect2
- CCDC136 | c.3012G>A p.S1004= | Silent (SNP) | VAF 33/183 reads (18%) | catalogued as rs192407933, COSV52805137; called by muse, mutect2, varscan2
- CCDC91 | c.621C>T p.H207= | Silent (SNP) | VAF 53/616 reads (9%) | catalogued as rs765831504, COSV60348662; called by muse, mutect2
- CD248 | c.1842C>T p.P614= | Silent (SNP) | VAF 43/217 reads (20%) | catalogued as rs767087914, COSV60936546; called by muse, mutect2, varscan2
- CEP128 | c.1353G>A p.A451= | Silent (SNP) | VAF 36/335 reads (11%) | catalogued as rs1015183931, COSV55390956; called by muse, mutect2, varscan2
- CERS1 | c.627C>T p.H209= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs774025010, COSV55930838; called by muse, mutect2
- CHD5 | c.4887G>A p.P1629= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs529230678, COSV52425195; called by mutect2, varscan2
- CHD8 | c.1320G>A p.S440= (on ENST00000646647 / NM_001170629.2; = p.S161= on NM_020920.4) | Silent (SNP) | VAF 40/372 reads (11%) | catalogued as rs898418482, COSV67872764; ClinVar: uncertain significance; called by mutect2, varscan2
- CHST6 | c.1143C>T p.N381= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59999663, COSV60001765; called by muse, mutect2, varscan2
- CLPTM1 | c.366G>A p.S122= | Silent (SNP) | VAF 37/241 reads (15%) | catalogued as rs751016937, COSV61613153; called by muse, mutect2, varscan2
- CNTNAP1 | c.645C>T p.A215= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1245765469, COSV52848713, COSV99226234; called by muse, mutect2, varscan2
- COL4A5 | c.1110A>G p.K370= | Silent (SNP) | VAF 157/177 reads (89%) | catalogued as COSV60360790, COSV60372418; called by muse, mutect2, varscan2
- CPA5 | c.471C>T p.S157= | Silent (SNP) | VAF 14/374 reads (4%) | catalogued as rs1554406533; called by muse, mutect2
- CSMD3 | c.7224G>A p.T2408= (on ENST00000297405 / NM_001363185.1; = p.T2304= on NM_052900.3) | Silent (SNP) | VAF 44/412 reads (11%) | catalogued as rs781779613, COSV52212247, COSV52298395; called by muse, mutect2
- CUBN | c.10029G>A p.P3343= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as rs370204059, COSV64721982; called by muse, mutect2, varscan2
- DAB2IP | c.2067C>T p.N689= (on ENST00000408936; = p.N661= on NM_032552.3) | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs142889743; called by muse, mutect2, varscan2
- DCAF8L2 | c.1473C>T p.C491= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs369119389, COSV70553004; called by muse, mutect2, varscan2
- DLG1 | c.597A>C p.P199= | Silent (SNP) | VAF 80/622 reads (13%) | catalogued as COSV58391670; called by muse, mutect2, varscan2
- DOP1B | c.3735G>A p.S1245= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs954807306, COSV101215327, COSV67694357; called by muse, mutect2, varscan2
- DUOX1 | c.2208C>T p.S736= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as rs372398306, COSV58477009; called by muse, mutect2, varscan2
- DYRK1A | c.927C>T p.G309= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as COSV58297242; called by muse, mutect2
- EIF4E1B | c.153G>A p.T51= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs372956251, COSV53781968; called by muse, mutect2, varscan2
- EIF5AL1 | c.381C>T p.Y127= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as rs780555804, COSV73123171; called by muse, mutect2
- ENOPH1 | c.504G>A p.T168= | Silent (SNP) | VAF 54/505 reads (11%) | catalogued as rs767238999, COSV56730383, COSV56732313; called by muse, mutect2, varscan2
- EPB41L4B | c.1935C>T p.D645= | Silent (SNP) | VAF 83/650 reads (13%) | catalogued as rs751739327, COSV65802286; called by muse, mutect2, varscan2
- EPHA7 | c.1932C>T p.F644= | Silent (SNP) | VAF 39/177 reads (22%) | catalogued as rs759807489, COSV65178824; called by muse, mutect2, varscan2
- ERCC2 | c.432G>A p.A144= | Silent (SNP) | VAF 33/195 reads (17%) | catalogued as rs372504564; called by muse, mutect2, varscan2
- FAM200B | c.1857G>A p.T619= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs370061923, COSV69959669; called by muse, mutect2, varscan2
- FAM83A | c.834G>A p.A278= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV52688206; called by mutect2, varscan2
- FANK1 | c.237G>A p.T79= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as rs371738419; called by muse, mutect2, varscan2
- FAT4 | c.450C>T p.S150= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV67900550; called by muse, mutect2
- FBLIM1 | c.1014C>T p.C338= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV60029966, COSV60030270; called by muse, mutect2, varscan2
- FBLN2 | c.1917C>T p.D639= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs200610728, COSV55485106; called by muse, mutect2, varscan2
- FBLN5 | c.468C>T p.T156= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as rs781009485, COSV50909623; called by muse, mutect2, varscan2
- FLNC | c.327C>T p.R109= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs750328194, COSV57960650; called by muse, mutect2, varscan2
- FREM2 | c.8055C>T p.P2685= | Silent (SNP) | VAF 21/247 reads (9%) | catalogued as rs148758281; called by muse, mutect2
- FSCN1 | c.1098G>A p.S366= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs563571642; called by muse, mutect2, varscan2
- GALR1 | c.198G>A p.P66= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV55319193; called by muse, mutect2
- GBP7 | c.294G>A p.T98= | Silent (SNP) | VAF 24/252 reads (10%) | catalogued as rs568032844, COSV54011952; called by muse, mutect2
- GEMIN5 | c.4317C>T p.T1439= | Silent (SNP) | VAF 48/498 reads (10%) | catalogued as rs757932154, COSV53565055; called by muse, mutect2
- GPR18 | c.648C>T p.H216= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs201170460, COSV61621415; called by muse, mutect2, varscan2
- H3C6 | c.138C>T p.T46= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1274889625; called by muse, varscan2
- HAPLN1 | c.993A>G p.A331= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV57152125; called by muse, mutect2, varscan2
- HGS | c.2196C>T p.I732= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as rs779416027, COSV61267389; called by muse, mutect2, varscan2
- HOXA5 | c.609G>A p.T203= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV56074861; called by muse, mutect2, varscan2
- IGHG2 | c.120G>A p.S40= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs749620407; called by muse, mutect2, varscan2
- IL15RA | c.315G>A p.A105= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as rs780860831, COSV66093219; called by muse, mutect2, varscan2
- ITPK1 | c.444C>T p.N148= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs760022527, COSV50900211; called by muse, mutect2, varscan2
- JAKMIP2 | c.396G>A p.A132= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs751130254, COSV54615788; called by muse, mutect2, varscan2
- JMY | c.2853C>T p.P951= | Silent (SNP) | VAF 24/201 reads (12%) | catalogued as rs181770929, COSV101267941, COSV68662553; called by muse, varscan2
- JRK | c.222G>A p.A74= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs781865813, COSV70629686; called by muse, mutect2
- KALRN | c.6078G>A p.P2026= (on ENST00000360013 / NM_001024660.4; = p.P329= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/200 reads (21%) | catalogued as rs762763041, COSV52262525, COSV52264802; called by muse, mutect2, varscan2
- KCNIP1 | c.405C>T p.H135= (on ENST00000411494 / NM_001034837.3; = p.H124= on NM_014592.4) | Silent (SNP) | VAF 54/348 reads (16%) | catalogued as rs376406374; called by muse, mutect2, varscan2
- KCNK13 | c.633C>T p.C211= | Silent (SNP) | VAF 29/186 reads (16%) | catalogued as rs149915166; called by muse, mutect2, varscan2
- KIAA0753 | c.1329C>T p.P443= | Silent (SNP) | VAF 36/299 reads (12%) | catalogued as rs745856829, COSV63818963; called by muse, mutect2, varscan2
- LHFPL3 | c.57G>A p.S19= | Silent (SNP) | VAF 8/145 reads (6%) | called by muse, mutect2
- LHX9 | c.624C>T p.S208= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs755594971, COSV61331617; called by muse, mutect2
- LILRB3 | c.60C>T p.R20= | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as rs1331297844; called by muse, mutect2, varscan2
- LRRC4B | c.786C>T p.H262= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs539448266, COSV65350824; called by muse, mutect2, varscan2
- LRRC75B | c.618G>A p.A206= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs767286236, COSV50641568; called by muse, mutect2, varscan2
- MAU2 | c.468G>A p.T156= | Silent (SNP) | VAF 39/198 reads (20%) | catalogued as rs199781947, COSV53237356; called by muse, mutect2, varscan2
- MCTP2 | c.681G>A p.T227= | Silent (SNP) | VAF 15/220 reads (7%) | catalogued as rs1418936905, COSV59149271; called by muse, mutect2
- MITF | c.492C>T p.G164= (on ENST00000448226 / NM_006722.3; = p.G58= on NM_000248.4) | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as rs373840246, COSV58831389; called by muse, mutect2, varscan2
- MKI67 | c.9669G>A p.T3223= | Silent (SNP) | VAF 31/240 reads (13%) | catalogued as rs778830596, COSV64077041; called by muse, mutect2, varscan2
- MMP13 | c.771C>T p.D257= | Silent (SNP) | VAF 154/350 reads (44%) | catalogued as rs150719050; called by muse, mutect2, varscan2
- MMP9 | c.1041C>T p.C347= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs770663427, COSV63434498; called by muse, mutect2, varscan2
- MYO7A | c.1143G>A p.T381= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs781795932, COSV68686577; called by muse, mutect2
- MYO9B | c.4935G>A p.S1645= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs1215485917, COSV68282842; called by muse, mutect2, varscan2
- NAA35 | c.1590C>T p.Y530= | Silent (SNP) | VAF 46/395 reads (12%) | catalogued as rs752952664, COSV64486379; called by muse, mutect2, varscan2
- NFIA | c.1035G>A p.A345= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs1051141398, COSV64537202; called by muse, mutect2, varscan2
- NOD2 | c.735G>A p.T245= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs773749264, COSV56048451; called by muse, mutect2, varscan2
- NPLOC4 | c.135G>A p.S45= | Silent (SNP) | VAF 30/259 reads (12%) | catalogued as COSV58619594; called by muse, mutect2, varscan2
- NRP1 | c.483C>T p.P161= | Silent (SNP) | VAF 90/389 reads (23%) | catalogued as rs1489288132, COSV55159320; called by muse, mutect2, varscan2
- OBSCN | c.10545C>T p.A3515= | Silent (SNP) | VAF 17/245 reads (7%) | catalogued as rs372698250; called by muse, mutect2
- OPN5 | c.444C>T p.H148= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs759743748, COSV55247486; called by mutect2, varscan2
- OR10J3 | c.726C>T p.C242= | Silent (SNP) | VAF 26/205 reads (13%) | catalogued as rs773890539, COSV59955216, COSV59955893; called by muse, mutect2, varscan2
- OR13A1 | c.297G>A p.A99= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs369298405; called by muse, mutect2, varscan2
- OR1D2 | c.174C>T p.P58= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs764544852, COSV58922528; called by muse, mutect2
- OR1D5 | c.451C>T p.L151= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV73859670; called by muse, mutect2, varscan2
- ORC1 | c.1998G>A p.R666= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV65365239; called by muse, mutect2
- OSBP2 | c.891C>T p.A297= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as rs540501472, COSV100213937, COSV60249782; called by muse, mutect2, varscan2
- PCDH17 | c.78G>A p.P26= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV64979384; called by muse, mutect2
- PCDHA9 | c.1125C>T p.I375= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV65332115; called by muse, mutect2
- PCDHGA7 | c.2202C>T p.N734= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV54036176, COSV99537528; called by muse, mutect2, varscan2
- PCDHGB5 | c.576G>A p.P192= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV54036190; called by muse, mutect2
- PCOLCE | c.681C>T p.D227= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1385114371; called by muse, mutect2, varscan2
- PDZRN3 | c.1551C>T p.N517= | Silent (SNP) | VAF 13/308 reads (4%) | called by muse, mutect2
- PEG10 | c.912C>T p.Y304= (on ENST00000482108 / NM_001040152.2; = p.Y338= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV71788715; called by muse, mutect2, varscan2
- PEG3 | c.810G>A p.T270= | Silent (SNP) | VAF 30/332 reads (9%) | catalogued as rs757349009, COSV55648121; called by muse, mutect2
- PER2 | c.3252C>T p.C1084= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as rs764150679, COSV54527926; called by muse, mutect2
- POPDC3 | c.507C>T p.G169= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as rs774623615, COSV54644674; called by muse, mutect2, varscan2
- PRDM12 | c.507C>T p.N169= | Silent (SNP) | VAF 31/244 reads (13%) | catalogued as rs369430134; called by muse, mutect2, varscan2
- PRDM6 | c.1395G>A p.S465= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as rs969513795, COSV68336266; called by muse, mutect2, varscan2
- PRICKLE1 | c.2217C>T p.S739= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as rs1415769760, COSV58210490; called by muse, mutect2, varscan2
- PRKDC | c.1182G>A p.Q394= | Silent (SNP) | VAF 24/269 reads (9%) | catalogued as COSV58064062; called by muse, mutect2
- PRPH2 | c.147C>T p.S49= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs372456408; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1182G>A p.P394= (on ENST00000352766; = p.P315= on NM_181334.5) | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs377295717; called by muse, mutect2, varscan2
- PRSS54 | c.243C>T p.I81= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1285964192, COSV54689735; called by muse, varscan2
- PTPRS | c.1374C>T p.R458= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs147314718; called by muse, mutect2
- RELB | c.942G>A p.P314= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs777844964, COSV55512214; called by muse, mutect2
- RHBDL1 | c.1281C>T p.Y427= (on ENST00000219551 / NM_001318733.2; = p.Y362= on NM_001278720.2) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs558802175, COSV53482812; called by muse, varscan2
- RHCG | c.393C>T p.C131= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs772870931, COSV51518472; called by muse, mutect2
- SACS | c.8883G>A p.S2961= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs1463204431, COSV66546898; called by muse, mutect2
- SLC16A6 | c.1095C>T p.C365= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as rs781876570, COSV59179505; called by muse, mutect2, varscan2
- SLC22A7 | c.357C>T p.Y119= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs374641067, COSV65355384; called by muse, mutect2, varscan2
- SLC29A4 | c.597G>A p.T199= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs371408782; called by muse, mutect2, varscan2
- SLC35C2 | c.327C>T p.T109= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs146236061, COSV99709169; called by muse, mutect2, varscan2
- SLC38A5 | c.276G>A p.S92= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs782434538, COSV58335645; called by muse, mutect2, varscan2
- SLFN11 | c.1794C>T p.H598= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs545992592; called by muse, mutect2, varscan2
- STAB1 | c.2190G>A p.T730= | Silent (SNP) | VAF 25/199 reads (13%) | catalogued as rs202162251, COSV58743234; called by muse, mutect2, varscan2
- STKLD1 | c.1281C>T p.P427= | Silent (SNP) | VAF 4/98 reads (4%) | catalogued as rs140796131, COSV64241618; called by muse, mutect2
- SV2A | c.714G>A p.S238= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as rs782330239; called by muse, mutect2
- TAS2R13 | c.336G>A p.A112= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as rs762436956, COSV66831894; called by muse, mutect2, varscan2
- TAS2R41 | c.18G>A p.T6= | Silent (SNP) | VAF 37/229 reads (16%) | catalogued as rs912579168, COSV68765893; called by muse, mutect2, varscan2
- TCF7 | c.924C>T p.H308= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs143958428; called by muse, mutect2, varscan2
- TEKT1 | c.975C>T p.N325= | Silent (SNP) | VAF 34/304 reads (11%) | catalogued as rs766002981, COSV58621993; called by muse, mutect2, varscan2
- TENM2 | c.5142G>A p.T1714= (on ENST00000518659 / NM_001122679.2; = p.T1475= on NM_001080428.3) | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs547919706, COSV69126970; called by muse, mutect2
- TICAM1 | c.2049C>T p.H683= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs772973812, COSV50240510; called by muse, mutect2, varscan2
- TMEM143 | c.648C>T p.S216= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs771813497, COSV53158921; called by muse, mutect2, varscan2
- UBE2G2 | c.195G>A p.P65= | Silent (SNP) | VAF 30/222 reads (14%) | catalogued as rs782627070, COSV58368777; called by muse, mutect2, varscan2
- UNC45A | c.2085G>A p.P695= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs559062930, COSV67793926; called by muse, mutect2, varscan2
- UNC50 | c.372C>T p.G124= | Silent (SNP) | VAF 114/1156 reads (10%) | catalogued as rs777220898, COSV60831503; called by muse, varscan2
- UNC80 | c.6936C>T p.T2312= | Silent (SNP) | VAF 25/197 reads (13%) | catalogued as rs1048714718, COSV55906726; called by muse, mutect2, varscan2
- UXS1 | c.429C>T p.H143= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs368812339; called by muse, mutect2, varscan2
- VAC14 | c.1932C>T p.H644= | Silent (SNP) | VAF 69/294 reads (23%) | catalogued as rs371336240, COSV55757921; called by muse, mutect2, varscan2
- VSIG10L | c.1872C>T p.G624= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs778055038, COSV59474354; called by muse, mutect2, varscan2
- WAC | c.96G>A p.S32= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs201074071, COSV61567526; called by muse, mutect2, varscan2
- WDR88 | c.156G>A p.T52= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs1293948062, COSV50126981; called by muse, mutect2, varscan2
- XPOT | c.246G>A p.T82= | Silent (SNP) | VAF 33/268 reads (12%) | catalogued as rs761074080, COSV60343940; called by mutect2, varscan2
- ZBTB20 | c.1356C>T p.S452= (on ENST00000474710 / NM_001164342.2; = p.S379= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1199716259, COSV61869174; called by muse, varscan2
- ZBTB7C | c.87C>T p.H29= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs1301710758, COSV59688049; called by muse, mutect2, varscan2
- ZC3H7B | c.813G>A p.S271= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs142365909; called by muse, mutect2, varscan2
- ZNF28 | c.1650G>A p.P550= | Silent (SNP) | VAF 10/198 reads (5%) | catalogued as rs1158376987, COSV60421617; called by muse, mutect2
- ZNF71 | c.891G>A p.P297= | Silent (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- ZNF835 | c.735C>T p.T245= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV73379445; called by muse, mutect2
- ANK2 | c.2900+5142C>T | Intron (SNP) | VAF 14/325 reads (4%) | catalogued as rs1260904408; called by muse, mutect2
- ARPC2 | c.*24G>A | 3'UTR (SNP) | VAF 16/124 reads (13%) | catalogued as rs368620700; called by muse, mutect2, varscan2
- DLG4 | c.1479-23G>A | Intron (SNP) | VAF 14/157 reads (9%) | catalogued as rs762285058; called by muse, mutect2
- GUCY1B2 | n.1790C>T | RNA (SNP) | VAF 27/234 reads (12%) | catalogued as rs1026722955; called by muse, mutect2, varscan2
- H3-2 | c.*155C>T | 3'UTR (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- ITIH3 | c.-2C>T | 5'UTR (SNP) | VAF 27/259 reads (10%) | catalogued as rs756577207, COSV56258571; called by muse, mutect2, varscan2
- MEIS3 | c.859-43C>T | Intron (SNP) | VAF 7/28 reads (25%) | catalogued as COSV58984663; called by muse, mutect2, varscan2
- MROH1 | c.1142-7522C>T | Intron (SNP) | VAF 12/117 reads (10%) | catalogued as rs768407136, COSV58188446; called by muse, mutect2, varscan2
- OPRM1 | c.-247C>T | 5'UTR (SNP) | VAF 24/130 reads (18%) | catalogued as rs1162069020, COSV57685746; called by muse, mutect2, varscan2
- OR2W5 | n.673C>T | RNA (SNP) | VAF 14/163 reads (9%) | catalogued as rs201534844; called by muse, mutect2
- OSCAR | c.*432G>A | 3'UTR (SNP) | VAF 8/47 reads (17%) | catalogued as rs768264740, COSV52928471; called by muse, mutect2, varscan2
- PISD | c.322-1890_322-1873delinsACCTG | Intron (DEL) | VAF 14/63 reads (22%) | called by pindel, varscan2*
- PLOD2 | c.1501-997G>C | Intron (SNP) | VAF 36/356 reads (10%) | catalogued as COSV51469310, COSV99283376; called by muse, mutect2
- PRR12 | chr19:49594814 G>A | 5'Flank (SNP) | VAF 11/74 reads (15%) | catalogued as COSV55871776; called by muse, mutect2, varscan2
- RPP38 | chr10:15096589 C>T | 5'Flank (SNP) | VAF 23/228 reads (10%) | catalogued as rs755175414; called by muse, mutect2, varscan2
- TMEM184A | c.*619G>A | 3'UTR (SNP) | VAF 8/39 reads (21%) | catalogued as rs1259076208; called by muse, mutect2
- TP73-AS1 | n.1557G>A | RNA (SNP) | VAF 14/147 reads (10%) | catalogued as rs370516330; called by muse, mutect2, varscan2
- TPM3 | chr1:154159024 C>T | 3'Flank (SNP) | VAF 20/282 reads (7%) | catalogued as rs376509539; called by muse, mutect2
- ZBTB20 | c.-28C>T | 5'UTR (SNP) | VAF 29/288 reads (10%) | catalogued as rs150868987, COSV61869847; called by muse, mutect2, varscan2
